Somatic mutation profile of tumor specimen TCGA-DI-A0WH-01A (aliquot TCGA-DI-A0WH-01A-12D-A12J-09) from TCGA case TCGA-DI-A0WH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 64.9 years (23,692 days).
Specimen TCGA-DI-A0WH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0393592d-9703-4089-ae50-0e4e7b089493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A0WH-10B (Blood Derived Normal), aliquot TCGA-DI-A0WH-10B-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09fd4757-e438-478c-a14d-8b6e5e78bd1d

The open-access MAF lists 713 somatic variants for this specimen: 518 protein-altering or splice-affecting, 173 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 351, Silent 173, Frame Shift Del 107, Nonsense Mutation 19, Frame Shift Ins 14, Splice Site 13, In Frame Del 7, Intron 6, RNA 6, Splice Region 5, 3'Flank 4, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 35/91 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- DICER1 | c.4458dup p.S1487Ifs*5 | Frame Shift Ins (INS) | VAF 19/111 reads (17%) | catalogued as rs1131691197; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 55/117 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRIA3 | c.2440-2734C>T | Intron (SNP) | VAF 99/268 reads (37%) | catalogued as rs780680047, COSV52057540; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600del p.F201Sfs*9 | Frame Shift Del (DEL) | VAF 27/161 reads (17%) | catalogued as rs752657203, COSV52322249, COSV52323301; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- POMT1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs119462987, CM061917; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 40/170 reads (24%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TACR3 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 55/263 reads (21%) | catalogued as rs727505375, CM103250, COSV59200874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCB1 | c.1553A>G p.H518R | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV55949999; called by muse, mutect2, varscan2
- ABCC11 | c.2549T>C p.L850P | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV62322776; called by muse, mutect2, varscan2
- ACACB | c.4192del p.L1398Sfs*26 | Frame Shift Del (DEL) | VAF 79/208 reads (38%) | catalogued as rs1565953344, COSV58128358; called by mutect2, pindel, varscan2
- ACO1 | c.2629G>A p.G877R | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs764702759, COSV59379504; called by muse, mutect2, varscan2
- ACTC1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV51758756; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 112/306 reads (37%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADORA1 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58810071; called by muse, mutect2, varscan2
- AGAP3 | c.2543G>A p.C848Y (on ENST00000622464; = p.C884Y on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768423651, COSV52547377; called by muse, mutect2, varscan2
- AGRN | c.5200C>T p.R1734C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372565629, COSV65068404; ClinVar: uncertain significance; called by muse, varscan2
- AGRN | c.5226C>A p.D1742E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV65069248; called by muse, varscan2
- AKT1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV62573137; called by muse, mutect2, varscan2
- ALDH1A2 | c.71A>T p.H24L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV51080692, COSV99990763; called by muse, mutect2
- ALOX12 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52349478; called by muse, mutect2
- AMPD2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1190354546, COSV56646104; called by muse, mutect2, varscan2
- ANKRD11 | c.3233C>T p.A1078V | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs753662123, COSV56360062; called by muse, mutect2, varscan2
- ANKRD26 | c.3160A>G p.N1054D | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1445837224, COSV65775234; called by muse, mutect2
- ANKRD27 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745675301, COSV60129155; called by muse, mutect2, varscan2
- ANKS3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371517379; called by muse, mutect2, varscan2
- ANO5 | c.871T>A p.L291M | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61084449; called by muse, varscan2
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2
- AP1B1 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1204536209, COSV58014574; called by muse, mutect2
- AP1M1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs200460904, COSV52225294; called by muse, mutect2, varscan2
- AP3B2 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as rs1438032095, COSV55609098; called by muse, mutect2, varscan2
- APOB | c.2141G>T p.S714I | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779427901, COSV51933737; called by muse, mutect2, varscan2
- ARHGAP26 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.985); catalogued as COSV50828468; called by muse, mutect2, varscan2
- ARHGAP33 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs376360480; called by muse, mutect2, varscan2
- ARHGEF7 | c.715C>T p.R239C (on ENST00000375741 / NM_001113511.2; = p.R61C on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774717680, COSV54542532; called by muse, mutect2, varscan2
- ASB4 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746370299, COSV57943223; called by muse, mutect2, varscan2
- ATP2B3 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782009437, COSV54845568; called by muse, mutect2, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 36/163 reads (22%) | catalogued as rs1268253442; called by mutect2, pindel, varscan2
- AZIN1 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1456391137, COSV61479885; called by muse, mutect2
- BMP4 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs550226363, COSV55415802; called by muse, mutect2, varscan2
- BOD1L1 | c.4310G>A p.G1437D | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV50011135; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 20/92 reads (22%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP1 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56298419; called by muse, mutect2, varscan2
- BSN | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV56516875; called by muse, mutect2, varscan2
- BTBD1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 106/277 reads (38%) | catalogued as COSV104377761, COSV55602828; called by muse, mutect2, varscan2
- BTRC | c.1256G>A p.R419Q (on ENST00000370187 / NM_033637.4; = p.R383Q on NM_003939.5) | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.659); catalogued as rs376316565, COSV64579389; called by muse, mutect2, varscan2
- CACNA1C | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59713253; called by muse, mutect2, varscan2
- CACNA1I | c.3767T>C p.V1256A | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60806841; called by muse, mutect2, varscan2
- CADPS2 | c.3604T>A p.L1202I | Missense Mutation (SNP) | VAF 161/439 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV57361060; called by muse, mutect2, varscan2
- CAMSAP1 | c.1723T>C p.S575P | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV56721767; called by muse, mutect2
- CAPRIN1 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58219572; called by muse, mutect2
- CARD10 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.133); catalogued as COSV52656108; called by muse, mutect2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 27/165 reads (16%) | catalogued as rs749079180; called by mutect2, pindel, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCR8 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV58337129; called by muse, mutect2, varscan2
- CD93 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55664757; called by muse, mutect2, varscan2
- CDAN1 | c.2159T>C p.L720P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62331775; called by muse, mutect2, varscan2
- CDCA2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs773590003, COSV57945676; called by muse, mutect2, varscan2
- CDCA3 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV57528578; called by muse, mutect2, varscan2
- CELF2 | c.1178A>G p.Y393C (on ENST00000416382 / NM_001025077.3; = p.Y406C on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59973057; called by muse, mutect2
- CELSR3 | c.4025C>A p.A1342D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV50853343; called by muse, varscan2
- CELSR3 | c.4015G>A p.G1339R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV50853414; called by muse, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs1325731082; called by mutect2, varscan2
- CEP350 | c.5218C>T p.R1740W | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335053833, COSV62598697; called by muse, mutect2, varscan2
- CEP78 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52847053; called by muse, mutect2, varscan2
- CHAF1A | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56671859; called by muse, mutect2, varscan2
- CHD1L | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 157/382 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV63613768; called by muse, mutect2, varscan2
- CHD6 | c.7511C>T p.T2504M | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs150243429; called by muse, mutect2, varscan2
- CHEK1 | c.717A>G p.L239= | Splice Region (SNP) | VAF 4/56 reads (7%) | catalogued as COSV54023205; called by muse, mutect2
- CIZ1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV52971218; called by muse, mutect2
- CLRN3 | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 45/117 reads (38%) | catalogued as COSV64098509; called by muse, mutect2, varscan2
- CLVS1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 73/191 reads (38%) | catalogued as rs1460252234, COSV57974192; called by muse, mutect2, varscan2
- CMTM1 | c.180del p.F60Lfs*3 (on ENST00000457188 / NM_181269.3; = p.F177Lfs*3 on NM_052999.4) | Frame Shift Del (DEL) | VAF 47/258 reads (18%) | catalogued as rs773521289; called by mutect2, varscan2
- CNOT1 | c.600A>T p.Q200H | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV57769674; called by muse, mutect2, varscan2
- COL1A1 | c.3737G>A p.R1246Q | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs376524129, COSV56804451; called by muse, mutect2, varscan2
- COL26A1 | c.648dup p.G217Rfs*3 (on ENST00000313669 / NM_001278563.3; = p.G215Rfs*3 on NM_133457.4) | Frame Shift Ins (INS) | VAF 20/42 reads (48%) | catalogued as rs762324149; called by mutect2, varscan2
- COL4A2 | c.3270C>T p.F1090= | Splice Region (SNP) | VAF 98/251 reads (39%) | catalogued as rs762951574, COSV64627172; called by muse, mutect2, varscan2
- COPG1 | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745625314, COSV100135627, COSV59112995, COSV59113805; called by muse, mutect2, varscan2
- CPNE9 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs199587019, COSV56068317; called by muse, mutect2, varscan2
- CPS1 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV51808729; called by muse, mutect2, varscan2
- CPXM2 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765435589, COSV53855989, COSV99583222; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 334/867 reads (39%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRACR2A | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52912216; called by muse, mutect2, varscan2
- CRNN | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as rs371423696; called by muse, mutect2, varscan2
- CSDE1 | c.520C>T p.R174C (on ENST00000358528 / NM_001007553.3; = p.R143C on NM_007158.6) | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as rs770606954, COSV54739163; called by muse, mutect2, varscan2
- CSMD2 | c.4829A>G p.N1610S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1026180043, COSV53907113; called by muse, mutect2, varscan2
- CSMD3 | c.6259C>T p.H2087Y (on ENST00000297405 / NM_001363185.1; = p.H1983Y on NM_052900.3) | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV52165371; called by muse, mutect2, varscan2
- CTR9 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs372968145; called by muse, mutect2, varscan2
- CUEDC1 | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64226343; called by muse, mutect2, varscan2
- CWH43 | c.790T>C p.W264R | Missense Mutation (SNP) | VAF 20/744 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56938419; called by muse, mutect2
- CYP11B1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52826608, COSV99455455; called by muse, mutect2, varscan2
- DDI1 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as rs371239684, COSV100160769, COSV56374601; called by muse, mutect2, varscan2
- DDR2 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 54/580 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs775098890, COSV63369829; called by muse, mutect2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 35/222 reads (16%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHX9 | c.1796A>G p.D599G | Missense Mutation (SNP) | VAF 56/777 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs757918330, COSV62359232; called by muse, mutect2
- DICER1 | c.5463G>A p.M1821I | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV58618927; called by muse, mutect2, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DOCK5 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs751838448, COSV52400400; called by muse, mutect2, varscan2
- DOCK6 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs751572807, COSV53914041; called by muse, mutect2, varscan2
- DPYSL5 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56510441; called by muse, mutect2, varscan2
- DSE | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs755108093, COSV59063491; called by muse, mutect2, varscan2
- DUOX1 | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.123); catalogued as COSV58480092; called by muse, mutect2, varscan2
- DVL1 | c.1474C>T p.Q492* (on ENST00000378888 / NM_001330311.2; = p.Q467* on NM_004421.3) | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV59563142; called by muse, mutect2, varscan2
- DYNAP | c.275T>C p.L92P (on ENST00000321600; = p.L66P on NM_173629.3) | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58666324; called by muse, mutect2
- DYNC1H1 | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767021083, COSV64136492; called by muse, mutect2, varscan2
- DYRK2 | c.1219A>T p.S407C (on ENST00000344096 / NM_006482.3; = p.S334C on NM_003583.4) | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59845972; called by muse, mutect2, varscan2
- DZANK1 | c.652C>G p.R218G (on ENST00000262547 / NM_001099407.1; = p.R19G on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs190534960; called by muse, mutect2, varscan2
- E2F8 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV51463130; called by muse, mutect2, varscan2
- ECH1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776507377, COSV55489107; called by muse, mutect2, varscan2
- EPB41L2 | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61354949; called by muse, mutect2, varscan2
- EPX | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs376090047; called by muse, mutect2, varscan2
- ERAP1 | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV57085766; called by muse, mutect2, varscan2
- EVC | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs1351243545, COSV53829383; called by muse, mutect2, varscan2
- FAAH | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV54543910, COSV54546044; called by muse, mutect2, varscan2
- FAM126A | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as rs146436512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM98A | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53210043; called by muse, mutect2
- FANCE | c.544del p.Q182Rfs*114 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs1561789651, COSV100003664; called by mutect2, pindel
- FANCL | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52074096; called by muse, mutect2, varscan2
- FAT4 | c.10120A>G p.K3374E | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58682145; called by muse, mutect2, varscan2
- FBXL16 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60964382; called by muse, mutect2, varscan2
- FBXL19 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); catalogued as COSV57942078; called by muse, varscan2
- FCGR2A | c.760G>A p.V254M (on ENST00000271450 / NM_001136219.3; = p.V253M on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/1671 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.496); catalogued as COSV54838544; called by muse, mutect2
- FGF1 | c.104del p.G35Afs*4 | Frame Shift Del (DEL) | VAF 57/304 reads (19%) | catalogued as COSV61803250; called by mutect2, pindel, varscan2
- FGF12 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs779234025, COSV53162857; called by muse, mutect2, varscan2
- FLNB | c.7049A>G p.H2350R | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55878094; called by muse, mutect2, varscan2
- FN1 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 65/146 reads (45%) | catalogued as COSV60551777; called by muse, mutect2, varscan2
- FOXP1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1359632401, COSV59520337; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMD7 | c.150T>G p.H50Q | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as COSV53745835; called by muse, mutect2, varscan2
- GALNT15 | c.1328_1335del p.T443Rfs*11 | Frame Shift Del (DEL) | VAF 71/220 reads (32%) | catalogued as COSV60216745; called by mutect2, pindel, varscan2
- GC | c.726del p.V243Cfs*12 | Frame Shift Del (DEL) | VAF 42/249 reads (17%) | catalogued as rs1290895118; called by mutect2, pindel, varscan2
- GCC1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs768122012, COSV58462396; called by muse, mutect2, varscan2
- GCDH | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as rs762052524, COSV55819962; called by muse, mutect2
- GCNT2 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV65457137; called by muse, mutect2
- GDE1 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 50/269 reads (19%) | catalogued as rs777419553, COSV62059371; called by muse, mutect2, varscan2
- GDI1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50131054; called by muse, mutect2
- GGT6 | c.855G>T p.E285D (on ENST00000574154 / NM_001122890.3; = p.E253D on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV54597106; called by muse, mutect2, varscan2
- GLIS1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs747936449, COSV56547943; called by muse, mutect2, varscan2
- GMPS | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV55809178; called by muse, mutect2
- GNA12 | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV51740423; called by muse, mutect2, varscan2
- GOLGA1 | c.1244T>A p.L415Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65221175; called by muse, mutect2, varscan2
- GPAA1 | c.1165-1C>T p.X389_splice | Splice Site (SNP) | VAF 36/82 reads (44%) | catalogued as rs187027021, COSV60155632; called by muse, mutect2, varscan2
- GPR156 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV59939559; called by muse, mutect2
- GPR18 | c.639T>A p.N213K | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as COSV61621145; called by muse, mutect2, varscan2
- GREB1 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52185852; called by muse, mutect2, varscan2
- GRIN2B | c.2177T>G p.L726R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74205445; called by muse, mutect2, varscan2
- GRIN3A | c.3299A>G p.K1100R | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.115); catalogued as COSV62452996; called by muse, mutect2
- GRM2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs561666712, COSV56584562; called by muse, mutect2, varscan2
- GSTM3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 162/391 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs774303411, COSV56662055; called by muse, varscan2
- GTF3C1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 177/472 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1340597679, COSV62240781; called by muse, mutect2, varscan2
- H2AC14 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV60797598; called by muse, mutect2, varscan2
- H2AC21 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV58611890; called by muse, mutect2, varscan2
- H2BC8 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 144/357 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.962); catalogued as rs1254161770, COSV55126649; called by muse, mutect2, varscan2
- HAPLN2 | c.440-2A>G p.X147_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV54815631; called by muse, mutect2, varscan2
- HCFC1 | c.5152G>C p.A1718P | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV60071794; called by muse, mutect2, varscan2
- HDLBP | c.2542A>G p.T848A | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV60494883; called by muse, mutect2, varscan2
- HELB | c.2147A>G p.H716R | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV56073527; called by muse, mutect2, varscan2
- HERC1 | c.8759C>T p.A2920V | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs759461833, COSV71247550, COSV71247930; called by muse, mutect2, varscan2
- HERC2 | c.9037G>A p.V3013M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs543941865, COSV55321128; called by muse, mutect2, varscan2
- HFE | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58513082; called by muse, mutect2, varscan2
- HHIP | c.1910-2A>G p.X637_splice | Splice Site (SNP) | VAF 70/207 reads (34%) | catalogued as COSV56839043; called by muse, mutect2, varscan2
- HIVEP1 | c.7499G>A p.G2500D | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65100832; called by muse, mutect2, varscan2
- HLF | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287557489, COSV56829787; called by muse, mutect2, varscan2
- HMCN1 | c.5470+2T>C p.X1824_splice | Splice Site (SNP) | VAF 28/402 reads (7%) | catalogued as COSV54896203; called by muse, mutect2
- HS6ST1 | c.953A>G p.Q318R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1193118099, COSV52127978; called by muse, mutect2, varscan2
- HSPA8 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); catalogued as COSV57083756; called by muse, mutect2, varscan2
- HTR1E | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs778362756, COSV59506609; called by muse, mutect2, varscan2
- IDE | c.1793A>G p.E598G | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV56423045; called by muse, mutect2, varscan2
- IFT140 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.928); catalogued as rs1165864520, COSV68488094; called by muse, mutect2, varscan2
- IGFLR1 | c.720G>A p.R240= | Splice Region (SNP) | VAF 21/42 reads (50%) | catalogued as COSV53074699; called by muse, mutect2, varscan2
- IGHM | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); catalogued as rs1398324382; called by muse, mutect2, varscan2
- IL18R1 | c.1271-1G>A p.X424_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | catalogued as COSV52124283; called by muse, mutect2, varscan2
- IL21R | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV61968235, COSV61970027; called by muse, mutect2, varscan2
- IPO7 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV65684874; called by muse, mutect2, varscan2
- ITGA2 | c.3389T>C p.V1130A | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV56859119; called by muse, mutect2, varscan2
- ITIH5 | c.2522T>G p.L841R | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755424406, COSV53663437; called by muse, mutect2, varscan2
- JAG1 | c.1687C>A p.L563M | Missense Mutation (SNP) | VAF 153/376 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV54756241; called by muse, mutect2, varscan2
- JARID2 | c.2768T>C p.F923S | Missense Mutation (SNP) | VAF 131/293 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59188686; called by muse, mutect2, varscan2
- JPH4 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457713061, COSV62508670; called by muse, varscan2
- JUP | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199511559, COSV60277833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JUP | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60277842; called by muse, mutect2, varscan2
- KALRN | c.2954C>T p.A985V | Missense Mutation (SNP) | VAF 7/214 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1466309558, COSV53761678; called by muse, mutect2
- KBTBD3 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV73241376; called by muse, mutect2, varscan2
- KCTD1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 103/528 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587776998, CM132529, COSV58685677; called by muse, mutect2, varscan2
- KIF11 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53270343; called by muse, mutect2, varscan2
- KIF4B | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs779418962, COSV70528262; called by muse, mutect2, varscan2
- KLHL38 | c.1322T>C p.I441T | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58087140; called by muse, mutect2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLHL9 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV62921510; called by muse, mutect2, varscan2
- KLK15 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs139728606; called by muse, mutect2, varscan2
- KRT13 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 121/659 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55839790; called by muse, mutect2, varscan2
- KRT38 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs773055251, COSV55845905; called by muse, mutect2, varscan2
- LAMC1 | c.3613A>G p.N1205D | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.045); catalogued as COSV51139418; called by muse, mutect2
- LAMC2 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV51455030; called by muse, mutect2
- LARP1B | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV52796912; called by muse, mutect2, varscan2
- LCT | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 119/285 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs751898984, COSV51548234; called by muse, mutect2, varscan2
- LGR6 | c.662G>A p.R221H (on ENST00000367278 / NM_001017403.1; = p.R169H on NM_021636.3) | Missense Mutation (SNP) | VAF 97/423 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs372287043; called by muse, mutect2, varscan2
- LHX5 | c.962C>A p.T321K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV55662637; called by muse, varscan2
- LLGL1 | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.28); catalogued as rs984797366, COSV57497629; called by muse, mutect2, varscan2
- LMO2 | c.394G>T p.G132C (on ENST00000395833 / NM_001142315.2; = p.G201C on NM_005574.4) | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57646037; called by muse, mutect2
- LMO7 | c.1945T>C p.C649R (on ENST00000357063; = p.C379R on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535266; called by muse, mutect2, varscan2
- LONRF2 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV66540426; called by muse, varscan2
- LOXL3 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51207230; called by muse, mutect2
- LRP1B | c.12805+2T>C p.X4269_splice | Splice Site (SNP) | VAF 49/175 reads (28%) | catalogued as COSV67211926; called by muse, mutect2, varscan2
- LRP1B | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101257901, COSV67211932; called by muse, mutect2, varscan2
- LRRC7 | c.4609A>G p.K1537E (on ENST00000651989 / NM_001370785.2; = p.K1457E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50448081; called by muse, mutect2, varscan2
- LRRC8B | c.1604A>G p.Q535R | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1172531465, COSV58374519; called by muse, mutect2, varscan2
- LRRK2 | c.2129del p.N710Mfs*2 | Frame Shift Del (DEL) | VAF 99/291 reads (34%) | catalogued as COSV54153441; called by mutect2, pindel, varscan2
- LTBP1 | c.2821A>C p.I941L (on ENST00000404816 / NM_206943.4; = p.I615L on NM_000627.4) | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV63185450; called by muse, mutect2, varscan2
- LYL1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV53400017; called by muse, mutect2, varscan2
- LZTR1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771655758, COSV53146391; called by muse, mutect2, varscan2
- MAGI2 | c.1322T>A p.I441N | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62651779; called by muse, mutect2, varscan2
- MAP11 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs866454876, COSV57586222; called by muse, mutect2, varscan2
- MAP2K3 | c.260G>A p.G87D (on ENST00000342679 / NM_145109.3; = p.G58D on NM_002756.4) | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV57566444; called by muse, mutect2, varscan2
- MARF1 | c.2059T>C p.S687P | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60022801; called by muse, mutect2, varscan2
- MAT2B | c.456A>G p.I152M | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV55200637; called by muse, mutect2
- MBTPS1 | c.3129G>T p.Q1043H | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.965); catalogued as rs1284611010, COSV58570459; called by muse, mutect2, varscan2
- MCF2L | c.718A>G p.M240V (on ENST00000375608; = p.M208V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV65050357; called by muse, mutect2, varscan2
- MCM2 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54033463; called by muse, mutect2, varscan2
- ME3 | c.1729T>A p.S577T | Missense Mutation (SNP) | VAF 11/367 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV62772107; called by muse, mutect2
- MEGF10 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs763591436, COSV57245326, COSV99175084; called by muse, mutect2, varscan2
- MFN2 | c.450del p.S151Qfs*10 | Frame Shift Del (DEL) | VAF 43/138 reads (31%) | catalogued as COSV52422150; called by mutect2, pindel, varscan2
- MICAL1 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs768553414, COSV62193218; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MOK | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51964811; called by muse, mutect2, varscan2
- MPG | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772837868, COSV54738089; called by muse, mutect2, varscan2
- MTA1 | c.1353C>A p.H451Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.167); catalogued as rs773319840, COSV100495539, COSV58756985; called by muse, mutect2, varscan2
- MTHFR | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1430872491, CM000527, COSV64877580; called by muse, mutect2
- MTNR1B | c.429C>A p.C143* | Nonsense Mutation (SNP) | VAF 30/208 reads (14%) | catalogued as COSV57066299; called by muse, mutect2, varscan2
- MTX3 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs373600368; called by muse, mutect2, varscan2
- MUC17 | c.3002G>A p.S1001N | Missense Mutation (SNP) | VAF 240/528 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs780043914, COSV60286066; called by muse, mutect2, varscan2
- MUC4 | c.2488T>C p.F830L | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV62146723; called by muse, mutect2
- MYH13 | c.3107A>G p.D1036G | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52826868; called by muse, mutect2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs752868848; called by pindel, varscan2
- MYH7B | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs1441490755, COSV52679212; called by muse, mutect2
- MYO1D | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 10/358 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59011925; called by muse, mutect2
- MYO5B | c.719G>T p.R240M | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53217560, COSV53222372; called by muse, mutect2
- MYOM1 | c.2623C>T p.L875F | Missense Mutation (SNP) | VAF 165/366 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55290700; called by muse, mutect2, varscan2
- NAGA | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367943149; called by muse, mutect2, varscan2
- NALCN | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 191/505 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV51932238; called by muse, mutect2, varscan2
- NAT9 | c.515_517del p.E172del | In Frame Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs764527097; called by pindel, varscan2
- NATD1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV67540959; called by muse, varscan2
- NAV2 | c.4654del p.S1552Pfs*6 (on ENST00000396087 / NM_001244963.2; = p.S1529Pfs*6 on NM_145117.5) | Frame Shift Del (DEL) | VAF 56/169 reads (33%) | catalogued as COSV60656918; called by mutect2, pindel, varscan2
- NCAN | c.3637+2T>C p.X1213_splice | Splice Site (SNP) | VAF 60/168 reads (36%) | catalogued as COSV53050384; called by muse, mutect2, varscan2
- NCAPD3 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV73258361; called by muse, mutect2, varscan2
- NCKAP5L | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV60129274; called by muse, mutect2, varscan2
- NDRG4 | c.592C>A p.L198M (on ENST00000570248 / NM_001378344.1; = p.L230M on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV50747504; called by muse, mutect2, varscan2
- NDUFV1 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.232); catalogued as rs1222034135, COSV59595242; called by muse, mutect2, varscan2
- NEXN | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs746587731, COSV53942765; called by muse, mutect2, varscan2
- NLRP14 | c.1116C>A p.C372* | Nonsense Mutation (SNP) | VAF 63/162 reads (39%) | catalogued as COSV55066473; called by muse, mutect2, varscan2
- NME9 | c.749G>A p.G250D (on ENST00000333911 / NM_001349024.2; = p.G189D on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV58618222; called by muse, mutect2, varscan2
- NOTCH3 | c.3724C>T p.R1242C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs769660847; called by muse, mutect2
- NSMAF | c.2423T>C p.V808A | Missense Mutation (SNP) | VAF 10/344 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV50686292; called by muse, mutect2
- NTF3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58417505; called by muse, mutect2
- NTRK3 | c.1523T>C p.I508T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV58119961; called by muse, mutect2, varscan2
- NUDC | c.806T>A p.I269N | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57671269; called by muse, mutect2, varscan2
- OIP5 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV52970986; called by muse, mutect2, varscan2
- OLA1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375033952, COSV52969227; called by muse, mutect2, varscan2
- OLFM2 | c.1006T>C p.Y336H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV53430003; called by muse, mutect2, varscan2
- OLFM4 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV54577060; called by muse, mutect2, varscan2
- OR52K2 | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 11/337 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV57835033; called by muse, mutect2
- OR5F1 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs756073504, COSV53546271; called by muse, mutect2, varscan2
- OR7C2 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 70/464 reads (15%) | catalogued as rs747041500; called by mutect2, varscan2
- ORAI1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1555324161, COSV57491392; called by mutect2, varscan2
- OSCP1 | c.849G>T p.Q283H (on ENST00000356637 / NM_001330493.1; = p.Q273H on NM_145047.5) | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52485804; called by muse, mutect2, varscan2
- OSGEP | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV52832087; called by muse, mutect2
- OTUB1 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.116); catalogued as rs1332837418, COSV55359673, COSV99736687; called by muse, mutect2, varscan2
- PACSIN2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs991913266, COSV54318736; called by muse, mutect2, varscan2
- PAQR8 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV62442441; called by muse, mutect2
- PARP4 | c.2098G>T p.G700C | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67961562; called by muse, mutect2
- PBLD | c.393+1G>C p.X131_splice | Splice Site (SNP) | VAF 42/115 reads (37%) | catalogued as rs1341087290, COSV53265766; called by muse, mutect2, varscan2
- PCDHGA6 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.106); catalogued as rs769907625, COSV53937174, COSV54024971; called by muse, mutect2, varscan2
- PCDHGA7 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV53937182; called by muse, mutect2, varscan2
- PDE4DIP | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57692702; called by muse, mutect2
- PDGFRB | c.2911C>A p.Q971K | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV53833934; called by muse, mutect2, varscan2
- PDZD2 | c.3322del p.Q1108Sfs*17 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs1212611383; called by mutect2, pindel, varscan2
- PDZRN4 | c.782T>A p.I261N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV68405129; called by muse, mutect2, varscan2
- PHF8 | c.1049C>A p.P350H (on ENST00000357988 / NM_001184896.1; = p.P314H on NM_015107.3) | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57680624; called by muse, mutect2, varscan2
- PIH1D2 | c.195A>G p.I65M | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV54775389; called by muse, mutect2
- PIK3CG | c.2072T>A p.I691N | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745475345, COSV63247913; called by muse, mutect2, varscan2
- PIKFYVE | c.3685T>C p.S1229P | Missense Mutation (SNP) | VAF 11/369 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs901542341, COSV52240323; called by muse, mutect2
- PIM1 | c.876T>A p.D292E | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65165322; called by muse, mutect2, varscan2
- PLA2G4D | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1426196601, COSV51820440; called by muse, mutect2, varscan2
- PLCB1 | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62048494; called by muse, mutect2
- PLEKHG2 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52682211, COSV99218063; called by muse, mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs746342377, COSV56183473; called by mutect2, pindel, varscan2
- PLXNA2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as rs200909289, COSV65437484; called by muse, mutect2, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 119/370 reads (32%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- PNLDC1 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 116/245 reads (47%) | catalogued as COSV51705236; called by muse, mutect2, varscan2
- POLQ | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV51750559; called by muse, mutect2, varscan2
- POLR3B | c.3088G>A p.V1030I | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs760305780, COSV57276862; called by muse, mutect2, varscan2
- POLRMT | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV73933225, COSV73933750; called by muse, mutect2
- PPFIA2 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as COSV61030125; called by muse, mutect2, varscan2
- PPFIA2 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV61030135; called by muse, mutect2, varscan2
- PPTC7 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62826050; called by muse, mutect2, varscan2
- PRG4 | c.3544G>A p.A1182T | Missense Mutation (SNP) | VAF 48/632 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV63355423; called by muse, mutect2
- PRKD2 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs776997966, COSV52186378; called by muse, mutect2, varscan2
- PRORP | c.1035-1G>A p.X345_splice | Splice Site (SNP) | VAF 29/80 reads (36%) | catalogued as COSV51617650; called by muse, mutect2, varscan2
- PRPF8 | c.6379T>A p.Y2127N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV56773289; called by muse, mutect2, varscan2
- PSEN2 | c.1145G>C p.S382T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.76); catalogued as COSV100423407, COSV60915928; called by muse, varscan2
- PSMD6 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 182/470 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55759715; called by muse, mutect2, varscan2
- PSMD7 | c.530+2T>C p.X177_splice | Splice Site (SNP) | VAF 29/208 reads (14%) | catalogued as COSV54697551; called by muse, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 41/104 reads (39%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PTPRZ1 | c.5330G>A p.G1777D | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66435560; called by muse, mutect2, varscan2
- PXDN | c.3038C>T p.T1013I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs763704795, COSV53230968; called by muse, mutect2, varscan2
- PYGL | c.205A>T p.I69F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV53585591; called by muse, mutect2, varscan2
- RABEP2 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV62869220; called by muse, mutect2, varscan2
- RAD1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV57715124; called by muse, mutect2, varscan2
- RAD52 | c.313del p.V105Wfs*7 | Frame Shift Del (DEL) | VAF 59/323 reads (18%) | catalogued as COSV57272829; called by mutect2, pindel, varscan2
- RALGAPA2 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1428975140, COSV52495912; called by muse, mutect2
- RANBP6 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359664640, COSV52389162; called by muse, mutect2, varscan2
- RAP1A | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62726262; called by muse, mutect2, varscan2
- RASA2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV53939245; called by muse, mutect2, varscan2
- RBM23 | c.523G>A p.A175T (on ENST00000359890 / NM_001077351.2; = p.A159T on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV57127576; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 54/110 reads (49%) | catalogued as rs762006287; called by mutect2, varscan2
- RGS12 | c.3166G>A p.V1056I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs73193395, COSV58751640; called by muse, mutect2, varscan2
- RHPN2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs201089375, COSV54277949; called by muse, mutect2, varscan2
- RMDN3 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs144235442; called by muse, mutect2, varscan2
- RNF14 | c.931del p.R311Gfs*8 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | catalogued as rs1561553826, COSV61662156; called by mutect2, pindel, varscan2
- RNF220 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | catalogued as COSV59190380; called by muse, mutect2, varscan2
- RNF34 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs761059150, COSV63442363; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 55/95 reads (58%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROCK2 | c.2125A>G p.K709E | Missense Mutation (SNP) | VAF 90/519 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1460278753, COSV55078275; called by muse, mutect2, varscan2
- ROR2 | c.1700T>C p.M567T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.813); catalogued as rs756271109, COSV65218566; called by muse, mutect2, varscan2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA4 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53702614; called by muse, mutect2
- RRAGC | c.756+1G>A p.X252_splice | Splice Site (SNP) | VAF 18/116 reads (16%) | catalogued as COSV65931438; called by muse, mutect2, varscan2
- RRH | c.324del p.F108Lfs*18 | Frame Shift Del (DEL) | VAF 95/243 reads (39%) | catalogued as rs751964437; called by mutect2, varscan2
- RRM2 | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58816627; called by muse, mutect2, varscan2
- RSPH3 | c.281_282insT p.P96Afs*54 | Frame Shift Ins (INS) | VAF 62/173 reads (36%) | catalogued as COSV51922328; called by pindel, varscan2
- RTP1 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56618333; called by muse, mutect2, varscan2
- SAMD9L | c.2113T>C p.Y705H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs747418346, COSV59081173; called by muse, mutect2, varscan2
- SBSPON | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.602); catalogued as COSV52076311; called by muse, mutect2
- SCAP | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV55560919; called by muse, mutect2, varscan2
- SCARF1 | c.1786A>G p.T596A | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53958485; called by muse, mutect2, varscan2
- SCNN1A | c.1468T>C p.Y490H | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57435313; called by muse, mutect2
- SDK2 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs745999186, COSV66185159; called by muse, mutect2, varscan2
- SEC31A | c.1701G>A p.G567= (on ENST00000355196 / NM_001318120.1; = p.G528= on NM_016211.4) | Splice Region (SNP) | VAF 45/216 reads (21%) | catalogued as COSV52344870; called by muse, mutect2, varscan2
- SEL1L2 | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53151472; called by muse, mutect2, varscan2
- SELP | c.1093A>G p.M365V | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs6134; called by muse, mutect2, varscan2
- SEMA3D | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs150646719; called by muse, mutect2, varscan2
- SGMS2 | c.1088A>G p.K363R | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV62989241; called by muse, mutect2
- SHROOM3 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56028220; called by muse, mutect2, varscan2
- SIDT1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV53500733; called by muse, mutect2, varscan2
- SIPA1L1 | c.5248A>T p.M1750L | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.33); catalogued as COSV62169826; called by muse, mutect2
- SKA2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV57521366; called by muse, mutect2, varscan2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC23A2 | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57770978, COSV57773733; called by muse, mutect2, varscan2
- SLC25A34 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV53816815; called by muse, mutect2, varscan2
- SLC37A1 | c.953T>A p.I318N | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61402202; called by muse, mutect2, varscan2
- SLC39A8 | c.852del p.E285Sfs*8 | Frame Shift Del (DEL) | VAF 29/265 reads (11%) | catalogued as rs1560527212; called by mutect2, pindel, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A11 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66261673; called by muse, mutect2, varscan2
- SLITRK3 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53848007; called by muse, mutect2, varscan2
- SMARCA1 | c.2867C>A p.T956N | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV64411750; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 60/272 reads (22%) | catalogued as rs768873484; called by mutect2, varscan2
- SPAG5 | c.606_609del p.E203Sfs*18 | Frame Shift Del (DEL) | VAF 37/190 reads (19%) | catalogued as COSV58801448; called by mutect2, pindel, varscan2
- SPAG9 | c.3095A>G p.Q1032R (on ENST00000262013 / NM_001130528.3; = p.Q1018R on NM_003971.6) | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV56234676; called by muse, mutect2, varscan2
- SPATA31A1 | c.3507A>T p.Q1169H | Missense Mutation (SNP) | VAF 84/658 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV66533700; called by muse, mutect2, varscan2
- SPTBN4 | c.4877A>G p.Y1626C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58948193; called by muse, mutect2, varscan2
- SRC | c.361T>C p.W121R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62439722; called by muse, mutect2, varscan2
- STAT6 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as rs757430778, COSV55670098; called by muse, mutect2, varscan2
- STING1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767228149, COSV58172536; called by mutect2, varscan2
- STK36 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 18/730 reads (2%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55326069, COSV55328956; called by muse, mutect2
- STRN3 | c.1630A>G p.N544D (on ENST00000357479 / NM_001083893.2; = p.N460D on NM_014574.4) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV62579375; called by muse, mutect2
- STX6 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 141/725 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1412858849, COSV51111884; called by muse, mutect2, varscan2
- SUGP2 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.886); catalogued as COSV58257856; called by muse, mutect2, varscan2
- SUPT6H | c.3974A>G p.Y1325C | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58927123; called by muse, mutect2, varscan2
- SUPT6H | c.4828C>T p.Q1610* | Nonsense Mutation (SNP) | VAF 58/427 reads (14%) | catalogued as COSV56386419; called by muse, mutect2, varscan2
- TAT | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63532740; called by muse, mutect2
- TBC1D31 | c.3111G>T p.Q1037H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54865722; called by muse, mutect2
- TBX19 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 160/380 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV63197367; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | catalogued as rs748021112; called by mutect2, varscan2
- TEKT1 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV58623002; called by muse, mutect2, varscan2
- THEMIS2 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV61077676; called by muse, mutect2, varscan2
- TMC6 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs772282970, COSV59808821; called by muse, mutect2
- TMCC3 | c.394_396del p.K132del | In Frame Del (DEL) | VAF 56/177 reads (32%) | catalogued as rs757882715; called by pindel, varscan2
- TMED9 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs139647055; called by muse, mutect2, varscan2
- TMEM184A | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 47/423 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs563532171, COSV52471742; called by muse, mutect2, varscan2
- TMEM82 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs773126258, COSV53816827; called by muse, mutect2, varscan2
- TMPRSS13 | c.751A>G p.S251G | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV70626251; called by muse, mutect2, varscan2
- TMTC2 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs761817332, COSV100337626, COSV58267265; called by muse, mutect2
- TMX1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63284837, COSV63284915; called by muse, mutect2, varscan2
- TNFRSF11A | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54023079; called by muse, mutect2, varscan2
- TNKS | c.3447+2T>C p.X1149_splice | Splice Site (SNP) | VAF 13/254 reads (5%) | catalogued as COSV60056523; called by muse, mutect2
- TNNI1 | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV60189296; called by muse, mutect2, varscan2
- TNRC18 | c.8338G>A p.A2780T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60307289, COSV60309442; called by muse, varscan2
- TNS2 | c.1484del p.P495Rfs*25 (on ENST00000314250 / NM_170754.4; = p.P505Rfs*25 on NM_015319.2) | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | catalogued as rs758743608; called by mutect2, pindel, varscan2
- TOPBP1 | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV53435301; called by muse, mutect2
- TP73 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as COSV60700781; called by muse, mutect2, varscan2
- TPGS2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 33/177 reads (19%) | catalogued as rs772037545, COSV57540359; called by muse, mutect2, varscan2
- TPR | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 91/575 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV66601031; called by muse, mutect2, varscan2
- TRPA1 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51560402; called by muse, mutect2, varscan2
- TRRAP | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1554412837, COSV62838864; called by muse, mutect2, varscan2
- TRRAP | c.5060C>T p.A1687V (on ENST00000359863 / NM_001244580.1; = p.A1669V on NM_003496.3) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.109); catalogued as COSV62843404; called by muse, mutect2, varscan2
- TSC1 | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53766473; called by muse, mutect2, varscan2
- TSR2 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV64308574; called by muse, mutect2
- TTN | c.59431C>T p.P19811S (on ENST00000591111; = p.P12387S on NM_003319.4) | Missense Mutation (SNP) | VAF 46/141 reads (33%) | PolyPhen possibly damaging (0.592); catalogued as COSV59979698; called by muse, mutect2, varscan2
- TTN | c.42457G>A p.V14153I (on ENST00000591111; = p.V6729I on NM_003319.4) | Missense Mutation (SNP) | VAF 56/169 reads (33%) | PolyPhen benign (0.001); catalogued as rs727504878, COSV59991854; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTPAL | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52828724; called by muse, mutect2, varscan2
- TUBAL3 | c.1151T>C p.M384T | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.261); catalogued as rs782023017, COSV66814229; called by muse, mutect2
- TUBGCP4 | c.1345G>C p.G449R (on ENST00000260383 / NM_001286414.3; = p.G448R on NM_014444.5) | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53018824, COSV53019759; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | catalogued as rs760251146; called by mutect2, varscan2
- TYW1 | c.2109G>A p.W703* | Nonsense Mutation (SNP) | VAF 169/422 reads (40%) | catalogued as COSV62752353; called by muse, mutect2, varscan2
- UBAP2L | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 56/521 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV55171787; called by muse, mutect2, varscan2
- UGT1A3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs540607993, COSV59387847; called by muse, mutect2, varscan2
- UGT2B7 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 19/616 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59443156; called by muse, mutect2
- UNC13A | c.4540C>T p.Q1514* | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | catalogued as COSV53194150, COSV99409864; called by muse, mutect2, varscan2
- USP9X | c.2731A>G p.T911A | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV61068655; called by muse, mutect2, varscan2
- USP9X | c.5364del p.K1788Nfs*10 | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | catalogued as COSV61075559; called by mutect2, pindel, varscan2
- VWA3B | c.2782T>C p.S928P | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV68242528; called by muse, mutect2
- WASF3 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58965102; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs773064295, COSV51967888; called by pindel, varscan2
- WDR25 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs780668010, COSV58934366; called by muse, mutect2, varscan2
- WDR27 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1311352058, COSV61208093; called by muse, mutect2
- WDR55 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as rs367668945; called by mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | catalogued as rs746919573; called by mutect2, varscan2
- XIRP2 | c.9276G>T p.K3092N (on ENST00000628543; = p.K3267N on NM_152381.6) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54696543; called by muse, mutect2, varscan2
- XRCC4 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56537215; called by muse, mutect2, varscan2
- YJU2 | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53606035; called by muse, mutect2, varscan2
- ZBTB4 | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV60140030; called by muse, mutect2, varscan2
- ZC3H12B | c.698T>C p.F233S | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV59047597; called by muse, mutect2
- ZFAT | c.3121T>G p.L1041V | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as COSV64737741; called by muse, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 41/176 reads (23%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYM4 | c.2564A>T p.D855V | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV58909789; called by muse, mutect2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 138/350 reads (39%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF182 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100527109, COSV59357035; called by muse, mutect2, varscan2
- ZNF207 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV58299722; called by muse, mutect2
- ZNF236 | c.4234del p.E1412Sfs*36 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as COSV53492072; called by mutect2, pindel, varscan2
- ZNF3 | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 103/268 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52795712; called by muse, mutect2, varscan2
- ZNF320 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1216418195, COSV67088010, COSV67088339; called by muse, mutect2, varscan2
- ZNF45 | c.1326del p.K442Nfs*98 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as COSV54193149; called by pindel, varscan2
- ZNF548 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60240830; called by muse, mutect2, varscan2
- ZNF557 | c.1069A>G p.T357A (on ENST00000414706 / NM_001044388.2; = p.T364A on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV53273734; called by muse, mutect2, varscan2
- ZNF561 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 30/287 reads (10%) | catalogued as COSV57177618; called by muse, mutect2, varscan2
- ZNF564 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.045); catalogued as COSV59434910; called by muse, mutect2, varscan2
- ZNF618 | c.1613C>T p.T538I (on ENST00000374126 / NM_001318042.2; = p.T445I on NM_133374.2) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55920490; called by muse, mutect2, varscan2
- ZNF695 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 21/386 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV60585705; called by muse, mutect2
- ZNF699 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV58025505; called by muse, mutect2, varscan2
- ZNF710 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51562822; called by muse, mutect2, varscan2
- ZNF813 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 107/725 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1162952130, COSV67176404; called by muse, mutect2, varscan2
- ZSCAN26 | c.1273A>G p.N425D (on ENST00000623276 / NM_001111039.2; = p.N291D on NM_152736.5) | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV52552779; called by muse, mutect2
- ZSWIM8 | c.4366A>G p.M1456V (on ENST00000605216 / NM_001242487.2; = p.M1461V on NM_015037.3) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55214135; called by muse, mutect2, varscan2
- AC007040.2 | c.423del p.F141Lfs*22 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- ANK3 | c.11496_11497del p.V3834Tfs*9 | Frame Shift Del (DEL) | VAF 61/541 reads (11%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.3332del p.P1111Lfs*5 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- ARIH2 | c.69_71dup p.E29dup | In Frame Ins (INS) | VAF 25/82 reads (30%) | called by pindel, varscan2
- ARL8B | c.439dup p.M147Nfs*9 | Frame Shift Ins (INS) | VAF 91/292 reads (31%) | called by mutect2, pindel, varscan2
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 52/590 reads (9%) | called by mutect2, pindel
- B3GNT4 | c.789dup p.P264Tfs*36 | Frame Shift Ins (INS) | VAF 62/177 reads (35%) | called by mutect2, pindel, varscan2
- BCL9 | c.2500_2501dup p.P835Lfs*30 | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | called by pindel, varscan2
- BCORL1 | c.3054del p.K1019Rfs*31 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | called by mutect2, pindel, varscan2
- BRWD1 | c.1058del p.L353Wfs*19 | Frame Shift Del (DEL) | VAF 30/182 reads (16%) | called by mutect2, pindel, varscan2
- CACNA1D | c.2569del p.I857Lfs*21 (on ENST00000350061 / NM_001128840.3; = p.I877Lfs*21 on NM_000720.4) | Frame Shift Del (DEL) | VAF 28/179 reads (16%) | called by mutect2, pindel, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 32/191 reads (17%) | called by mutect2, pindel, varscan2
- CCL11 | c.63del p.L22Sfs*25 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | called by mutect2, pindel
- CCR3 | c.368dup p.I124Hfs*45 | Frame Shift Ins (INS) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- CENPK | c.350dup p.L118Vfs*14 | Frame Shift Ins (INS) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- CENPK | c.232del p.T78Hfs*7 | Frame Shift Del (DEL) | VAF 23/146 reads (16%) | called by mutect2, pindel, varscan2
- CFAP97 | c.930del p.E313Kfs*15 | Frame Shift Del (DEL) | VAF 28/245 reads (11%) | called by mutect2, pindel, varscan2
- CHPF2 | c.69del p.C24Afs*3 | Frame Shift Del (DEL) | VAF 28/145 reads (19%) | called by mutect2, pindel, varscan2
- DGAT2L6 | c.766del p.I256Sfs*4 | Frame Shift Del (DEL) | VAF 57/182 reads (31%) | called by mutect2, pindel, varscan2
- DMBT1 | c.7604del p.P2535Hfs*24 (on ENST00000338354 / NM_001377530.1; = p.P1778Hfs*24 on NM_004406.3) | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- EFHC1 | c.1221del p.D408Tfs*7 | Frame Shift Del (DEL) | VAF 39/299 reads (13%) | called by mutect2, pindel, varscan2
- ESCO1 | c.968del p.K323Rfs*9 | Frame Shift Del (DEL) | VAF 37/164 reads (23%) | called by mutect2, pindel, varscan2
- FAM133A | c.157dup p.T53Nfs*8 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, varscan2
- FAM168A | c.366del p.Y123Tfs*89 (on ENST00000064778 / NM_001286050.2; = p.Y114Tfs*89 on NM_015159.3) | Frame Shift Del (DEL) | VAF 22/175 reads (13%) | called by mutect2, pindel, varscan2
- FHDC1 | c.304del p.W102Gfs*55 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- FOXP1 | c.1240del p.L414* | Frame Shift Del (DEL) | VAF 48/260 reads (18%) | called by mutect2, pindel, varscan2
- FRAS1 | c.5574del p.F1858Lfs*17 | Frame Shift Del (DEL) | VAF 114/302 reads (38%) | called by mutect2, varscan2
- HAAO | c.728del p.G243Dfs*4 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- HECTD1 | c.6813del p.F2271Lfs*13 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- HOXA10 | c.1057_1059del p.K353del | In Frame Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel, varscan2
- HS3ST5 | c.930del p.R311Afs*33 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- ING5 | c.388del p.G131Afs*69 | Frame Shift Del (DEL) | VAF 35/224 reads (16%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- INTS1 | c.2527dup p.R843Pfs*31 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- ITPKB | c.1002_1004del p.E334del | In Frame Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- KCNH1 | c.2185del p.L729* (on ENST00000271751 / NM_172362.3; = p.L702* on NM_002238.4) | Frame Shift Del (DEL) | VAF 44/233 reads (19%) | called by pindel, varscan2
- KCNH8 | c.1656del p.F552Lfs*62 | Frame Shift Del (DEL) | VAF 34/244 reads (14%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.4274dup p.S1426Lfs*14 | Frame Shift Ins (INS) | VAF 39/278 reads (14%) | called by mutect2, pindel, varscan2
- KIF26A | c.4468del p.A1490Pfs*14 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- LAMA3 | c.7738del p.T2580Hfs*68 (on ENST00000313654 / NM_198129.4; = p.T971Hfs*68 on NM_000227.6) | Frame Shift Del (DEL) | VAF 67/175 reads (38%) | called by mutect2, pindel, varscan2
- LRIG3 | c.1212del p.A405Pfs*11 | Frame Shift Del (DEL) | VAF 61/155 reads (39%) | called by mutect2, pindel, varscan2
- MAP1B | c.5901del p.E1968Kfs*2 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- MTREX | c.228del p.F76Lfs*7 | Frame Shift Del (DEL) | VAF 79/234 reads (34%) | called by mutect2, pindel, varscan2
- MYO3B | c.1231del p.H411Tfs*38 | Frame Shift Del (DEL) | VAF 34/283 reads (12%) | called by mutect2, pindel, varscan2
- MYT1L | c.2653dup p.L885Pfs*25 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.2276dup p.N759Kfs*2 | Frame Shift Ins (INS) | VAF 102/318 reads (32%) | called by mutect2, pindel, varscan2
- PANK1 | c.1199del p.K400Sfs*23 (on ENST00000307534 / NM_148977.2; = p.K175Sfs*23 on NM_138316.4) | Frame Shift Del (DEL) | VAF 118/374 reads (32%) | called by mutect2, pindel, varscan2
- PPARGC1B | c.2371_2372del p.V791Lfs*2 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- PPEF1 | c.1895del p.L632* | Frame Shift Del (DEL) | VAF 34/276 reads (12%) | called by mutect2, pindel, varscan2
- PRRT3 | c.1092del p.K365Sfs*14 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- QPCTL | c.630del p.K210Nfs*6 | Frame Shift Del (DEL) | VAF 44/98 reads (45%) | called by mutect2, pindel, varscan2
- RAD51AP1 | c.208dup p.R70Kfs*4 (on ENST00000228843 / NM_001130862.2; = p.R70Kfs*6 on NM_006479.5) | Frame Shift Ins (INS) | VAF 14/79 reads (18%) | called by mutect2, varscan2
- RBM28 | c.1795del p.M599* | Frame Shift Del (DEL) | VAF 21/115 reads (18%) | called by mutect2, pindel, varscan2
- SCAF8 | c.2036del p.L679* | Frame Shift Del (DEL) | VAF 43/315 reads (14%) | called by mutect2, varscan2
- SHOC1 | c.3108del p.V1037Ffs*25 | Frame Shift Del (DEL) | VAF 59/167 reads (35%) | called by mutect2, pindel, varscan2
- SMARCD3 | c.1150_1152del p.E384del (on ENST00000262188 / NM_001003801.2; = p.E371del on NM_003078.4) | In Frame Del (DEL) | VAF 77/207 reads (37%) | called by mutect2, pindel, varscan2
- SPARCL1 | c.20del p.F7Sfs*29 | Frame Shift Del (DEL) | VAF 32/195 reads (16%) | called by mutect2, pindel, varscan2
- SPRED1 | c.234del p.D79Tfs*42 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | called by mutect2, pindel, varscan2
- ST7L | c.218del p.L73* | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- SV2C | c.1551del p.F517Lfs*9 | Frame Shift Del (DEL) | VAF 141/403 reads (35%) | called by mutect2, pindel, varscan2
- SYMPK | c.2152_2154del p.L718del | In Frame Del (DEL) | VAF 30/172 reads (17%) | called by pindel, varscan2
- TAF9 | c.166del p.I56Ffs*38 | Frame Shift Del (DEL) | VAF 21/144 reads (15%) | called by mutect2, pindel, varscan2
- TEX15 | c.7138del p.R2380Efs*4 (on ENST00000256246; = p.R2763Efs*4 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 50/303 reads (17%) | called by mutect2, pindel, varscan2
- TMA16 | c.37del p.E13Kfs*28 | Frame Shift Del (DEL) | VAF 68/217 reads (31%) | called by mutect2, pindel, varscan2
- TMPRSS11D | c.935del p.G312Afs*13 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.275del p.P92Lfs*6 | Frame Shift Del (DEL) | VAF 35/177 reads (20%) | called by mutect2, pindel, varscan2
- TRIM59 | c.1119_1120del p.S374Ffs*3 | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- TSEN2 | c.1149_1151del p.I384del | In Frame Del (DEL) | VAF 41/207 reads (20%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.2705del p.N902Mfs*16 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- A2ML1 | c.603T>C p.A201= | Silent (SNP) | VAF 51/303 reads (17%) | catalogued as COSV55289860; called by muse, mutect2, varscan2
- ABCA6 | c.4422T>C p.A1474= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV52638046; called by muse, mutect2, varscan2
- ABHD4 | c.738C>T p.N246= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as rs746883580, COSV53529327; called by muse, mutect2, varscan2
- ABLIM2 | c.258C>T p.C86= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs774551878, COSV56403488; called by muse, mutect2, varscan2
- ADGRL1 | c.1764G>T p.L588= (on ENST00000340736 / NM_001008701.3; = p.L583= on NM_014921.5) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV61564499; called by muse, varscan2
- AHNAK2 | c.14019T>C p.H4673= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs765408572, COSV60914243; called by muse, mutect2, varscan2
- AHNAK2 | c.7344C>T p.S2448= | Silent (SNP) | VAF 46/229 reads (20%) | catalogued as rs578259727, COSV60911392; called by muse, mutect2, varscan2
- AHNAK2 | c.3129C>A p.T1043= | Silent (SNP) | VAF 53/247 reads (21%) | catalogued as COSV60914252; called by muse, mutect2, varscan2
- AOC1 | c.1717C>T p.L573= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV62868322; called by muse, mutect2, varscan2
- AP4E1 | c.2295G>A p.L765= | Silent (SNP) | VAF 50/217 reads (23%) | catalogued as COSV55916680; called by muse, mutect2, varscan2
- APRT | c.388C>T p.L130= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV51937296; called by muse, mutect2, varscan2
- ARAP1 | c.375G>A p.P125= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs749937039, COSV61990899; called by muse, varscan2
- ARHGEF12 | c.3547T>C p.L1183= | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as COSV63104245; called by muse, mutect2, varscan2
- ARHGEF15 | c.780C>T p.A260= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs768476171, COSV62725029, COSV62725049; called by muse, mutect2, varscan2
- ARHGEF18 | c.756C>T p.C252= (on ENST00000359920 / NM_001130955.2; = p.C148= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1473197793, COSV60469360; called by muse, mutect2, varscan2
- ARMC4 | c.771T>C p.G257= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV53464729; called by muse, mutect2, varscan2
- ARMH3 | c.1231T>C p.L411= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV64234570; called by muse, mutect2
- ASB11 | c.492C>A p.A164= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV60355003; called by muse, mutect2
- ATR | c.219G>A p.Q73= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as COSV63386065; called by muse, mutect2, varscan2
- ATRN | c.3093C>A p.A1031= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV53527220; called by muse, mutect2, varscan2
- ATRNL1 | c.4011G>A p.G1337= | Silent (SNP) | VAF 10/282 reads (4%) | catalogued as rs1404669690, COSV58085429; called by muse, mutect2
- BARX1 | c.639C>T p.P213= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV54158935; called by muse, mutect2, varscan2
- BCL9 | c.1626T>C p.H542= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV52343617; called by muse, mutect2, varscan2
- BICD1 | c.1176C>T p.D392= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as rs199850858; called by muse, varscan2
- BLMH | c.1113C>G p.T371= | Silent (SNP) | VAF 79/214 reads (37%) | catalogued as COSV55585302; called by muse, mutect2, varscan2
- CABYR | c.855T>C p.I285= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as COSV59110837; called by muse, mutect2
- CASKIN1 | c.687G>A p.A229= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as rs1162895618, COSV58872163; called by muse, mutect2
- CASP9 | c.465G>T p.L155= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61601380; called by muse, mutect2, varscan2
- CCDC22 | c.1044T>C p.I348= | Silent (SNP) | VAF 8/181 reads (4%) | catalogued as rs782294044, COSV66051226; ClinVar: likely benign; called by muse, mutect2
- CCDC34 | c.196C>T p.L66= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as rs756508199, COSV58725644; called by muse, mutect2, varscan2
- CCDC50 | c.78C>T p.D26= | Silent (SNP) | VAF 213/476 reads (45%) | catalogued as COSV66667802; called by muse, varscan2
- CDC45 | c.1527C>T p.I509= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV54245063; called by muse, mutect2, varscan2
- CDH11 | c.1863C>T p.I621= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs866544694, COSV51753477; called by muse, varscan2
- CDH11 | c.1815C>T p.N605= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs751479928, COSV51755698; called by muse, varscan2
- CEP85 | c.1989A>G p.S663= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV53329034; called by muse, mutect2, varscan2
- CERS2 | c.1059G>A p.E353= | Silent (SNP) | VAF 171/396 reads (43%) | catalogued as COSV54981734; called by muse, mutect2, varscan2
- CNGA4 | c.757C>T p.L253= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV66005798; called by muse, mutect2, varscan2
- CORO2A | c.612T>C p.I204= | Silent (SNP) | VAF 123/294 reads (42%) | catalogued as COSV59663057; called by muse, mutect2, varscan2
- CRP | c.99G>A p.S33= | Silent (SNP) | VAF 32/249 reads (13%) | catalogued as rs1309388012, COSV54813343; called by muse, mutect2, varscan2
- CSMD1 | c.7419C>T p.T2473= (on ENST00000520002; = p.T2472= on NM_033225.6) | Silent (SNP) | VAF 38/180 reads (21%) | catalogued as COSV59315889; called by muse, mutect2, varscan2
- CSRNP1 | c.1689C>A p.A563= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV56187941; called by muse, mutect2, varscan2
- CYP4F22 | c.111C>A p.R37= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as COSV54108113; called by muse, mutect2, varscan2
- DCUN1D5 | c.336A>G p.S112= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as rs1236190990, COSV52784413; called by muse, mutect2, varscan2
- DLG5 | c.5421G>A p.K1807= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV64947770; called by muse, mutect2
- DOP1B | c.4617A>G p.T1539= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV67693133; called by muse, mutect2, varscan2
- ELN | c.2166C>T p.A722= (on ENST00000320399 / NM_001278939.1; = p.A689= on NM_000501.4) | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as rs782657493, COSV52709719; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENAM | c.1464T>C p.V488= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV68535815; called by muse, mutect2, varscan2
- EZH1 | c.1311T>C p.A437= | Silent (SNP) | VAF 10/308 reads (3%) | catalogued as COSV70549238; called by muse, mutect2
- FAM124A | c.96G>A p.T32= | Silent (SNP) | VAF 89/256 reads (35%) | catalogued as rs768068704, COSV54474197, COSV54476125; called by muse, mutect2, varscan2
- FAM135A | c.2583T>C p.P861= (on ENST00000370479 / NM_001351599.1; = p.P648= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV52050667; called by muse, mutect2, varscan2
- FAM47C | c.1605C>T p.H535= | Silent (SNP) | VAF 55/246 reads (22%) | catalogued as COSV63726178, COSV63729764; called by muse, mutect2, varscan2
- FBXL12 | c.711G>A p.V237= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV56114044; called by muse, mutect2, varscan2
- FCGRT | c.321A>G p.G107= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs767826358, COSV55529478; called by muse, mutect2, varscan2
- FEM1C | c.120T>C p.N40= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV57231447; called by muse, mutect2, varscan2
- GALK1 | c.1032G>A p.T344= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs771995336, COSV52325155; called by muse, mutect2, varscan2
- HMCN1 | c.15363C>T p.C5121= | Silent (SNP) | VAF 63/325 reads (19%) | catalogued as COSV54896211; called by muse, mutect2, varscan2
- HMGCLL1 | c.27G>A p.K9= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV51444185; called by muse, mutect2, varscan2
- HOMER3 | c.627C>T p.A209= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs757306783, COSV55355869; called by muse, varscan2
- HS6ST2 | c.648G>A p.L216= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs1283534915, COSV63712588; called by muse, mutect2, varscan2
- IFT140 | c.2214C>T p.D738= | Silent (SNP) | VAF 71/206 reads (34%) | catalogued as rs141087126; called by muse, mutect2, varscan2
- IL17F | c.72T>C p.F24= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV60234083; called by muse, mutect2
- INPP5F | c.102T>C p.T34= | Silent (SNP) | VAF 169/446 reads (38%) | catalogued as COSV62820965; called by muse, mutect2, varscan2
- IPCEF1 | c.513C>T p.H171= | Silent (SNP) | VAF 66/359 reads (18%) | catalogued as rs761835449, COSV54543544; called by muse, mutect2, varscan2
- KATNIP | c.3705C>T p.G1235= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV55179330; called by muse, mutect2
- KAZN | c.1953C>T p.A651= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs764138893, COSV65718427; called by muse, mutect2, varscan2
- KDM3B | c.1374G>T p.S458= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs745953070, COSV100069378, COSV58690120; called by muse, mutect2, varscan2
- KDM6A | c.576A>G p.L192= | Silent (SNP) | VAF 215/585 reads (37%) | catalogued as COSV65039673; called by muse, mutect2, varscan2
- KDM7A | c.2331T>C p.H777= | Silent (SNP) | VAF 139/318 reads (44%) | catalogued as COSV50091107; called by muse, mutect2, varscan2
- KIF18B | c.414G>A p.R138= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV59272723; called by muse, mutect2
- KLHL9 | c.1125G>A p.R375= | Silent (SNP) | VAF 55/156 reads (35%) | catalogued as COSV62921359; called by muse, mutect2, varscan2
- KRT31 | c.393C>T p.I131= | Silent (SNP) | VAF 24/334 reads (7%) | catalogued as rs553792126, COSV52433404; called by muse, mutect2
- LARP4 | c.2085G>A p.Q695= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV53322204; called by muse, mutect2, varscan2
- LIMD1 | c.1971C>T p.C657= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV56267049; called by muse, mutect2, varscan2
- LRP2 | c.5700C>T p.I1900= | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as rs772934176, COSV55551011; called by muse, mutect2, varscan2
- LRP4 | c.4869C>T p.G1623= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV66135499; called by muse, mutect2
- LRRC4 | c.393C>T p.F131= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as rs1422869407, COSV50813762; called by muse, mutect2, varscan2
- LRRK1 | c.5470C>T p.L1824= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV52609289; called by muse, mutect2, varscan2
- LSMEM2 | c.33T>C p.L11= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV57113536; called by muse, mutect2
- MADD | c.1407G>A p.P469= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs145712827; called by muse, mutect2, varscan2
- MAST1 | c.1167C>T p.Y389= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV52245937, COSV99263129; called by muse, mutect2, varscan2
- MAST2 | c.222T>C p.S74= | Silent (SNP) | VAF 10/282 reads (4%) | catalogued as COSV63617894; called by muse, mutect2
- MED12 | c.6309A>G p.Q2103= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs1273622444, COSV61332672; called by muse, varscan2
- MED12 | c.6393C>A p.P2131= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as COSV61338500; called by muse, varscan2
- MEP1A | c.1590G>A p.S530= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs756665276, COSV57919116; called by muse, mutect2, varscan2
- MMP14 | c.441G>A p.A147= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs781697049, COSV61288153; called by muse, mutect2, varscan2
- MPPED1 | c.67C>T p.L23= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV61987451; called by muse, mutect2, varscan2
- MPPED1 | c.438C>T p.I146= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as rs369069551; called by muse, mutect2, varscan2
- MTMR1 | c.1194G>A p.A398= | Silent (SNP) | VAF 86/247 reads (35%) | catalogued as rs370523763, COSV64892397; called by muse, mutect2, varscan2
- MTNR1A | c.117G>A p.V39= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV56155807; called by muse, mutect2, varscan2
- MTUS1 | c.2079T>C p.G693= | Silent (SNP) | VAF 65/179 reads (36%) | catalogued as COSV50555639; called by muse, mutect2, varscan2
- MYBPC1 | c.3078C>T p.I1026= (on ENST00000550270 / NM_206820.2; = p.I1033= on NM_002465.4) | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as rs757074197, COSV62252683; called by muse, mutect2, varscan2
- MYH14 | c.351C>T p.N117= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs755596399, COSV51815901; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.7041A>G p.Q2347= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1245948872, COSV100123564, COSV59132468; called by muse, mutect2
- MYO5B | c.124C>T p.L42= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV53217565; called by muse, mutect2, varscan2
- MYOM1 | c.4521C>A p.T1507= | Silent (SNP) | VAF 10/286 reads (3%) | catalogued as COSV55290687; called by muse, mutect2
- NCF2 | c.1344T>C p.N448= | Silent (SNP) | VAF 21/764 reads (3%) | catalogued as COSV62315327; called by muse, mutect2
- NFATC2 | c.1677T>C p.S559= | Silent (SNP) | VAF 8/165 reads (5%) | catalogued as COSV65355435; called by muse, mutect2
- NINL | c.3093G>A p.P1031= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs143482574; called by muse, mutect2, varscan2
- NLE1 | c.288T>C p.A96= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV62604137; called by muse, mutect2, varscan2
- NRDE2 | c.1530G>A p.L510= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV62963000; called by muse, mutect2, varscan2
- NUDT16L1 | c.447C>A p.T149= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV52150504; called by muse, mutect2, varscan2
- NUP210L | c.243A>G p.L81= | Silent (SNP) | VAF 239/542 reads (44%) | catalogued as rs745385190, COSV55135807; called by muse, mutect2, varscan2
- NUP37 | c.711T>C p.I237= | Silent (SNP) | VAF 93/193 reads (48%) | catalogued as COSV51837638; called by muse, mutect2, varscan2
- OPCML | c.462C>T p.T154= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV59419919; called by muse, mutect2, varscan2
- OR13C8 | c.336C>T p.C112= | Silent (SNP) | VAF 10/277 reads (4%) | catalogued as COSV58611009; called by muse, mutect2
- OR2T3 | c.780C>A p.S260= | Silent (SNP) | VAF 278/1009 reads (28%) | catalogued as COSV62082312; called by muse, mutect2, varscan2
- OR7E24 | c.891T>C p.T297= | Silent (SNP) | VAF 77/191 reads (40%) | catalogued as COSV71702195, COSV71702270; called by muse, mutect2, varscan2
- P2RX1 | c.675C>A p.P225= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as rs200190306, COSV56653699; called by muse, mutect2, varscan2
- PAPPA2 | c.105T>C p.V35= | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as COSV62777328; called by muse, mutect2, varscan2
- PCDHA2 | c.1437G>A p.A479= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV100973853, COSV65366604; called by muse, mutect2, varscan2
- PCDHA8 | c.1734C>T p.S578= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs782136432, COSV65325913; called by muse, mutect2, varscan2
- PCDHB6 | c.1320C>T p.S440= | Silent (SNP) | VAF 76/206 reads (37%) | catalogued as rs146356849, COSV50693505; called by muse, varscan2
- PCDHB6 | c.1404C>T p.I468= | Silent (SNP) | VAF 74/154 reads (48%) | catalogued as rs1428955317, COSV50695222; called by muse, varscan2
- PDHA2 | c.1008T>C p.I336= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as COSV54778851; called by muse, mutect2, varscan2
- PHF21B | c.1167C>T p.G389= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs773819642, COSV57557945; called by muse, mutect2, varscan2
- PHF3 | c.6T>C p.D2= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV50317415; called by muse, mutect2, varscan2
- PHYH | c.573C>T p.C191= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1054747084, COSV53815570; called by muse, mutect2, varscan2
- PLCH2 | c.1044C>T p.D348= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs764296975, COSV53942248; called by muse, mutect2, varscan2
- PLRG1 | c.606G>A p.G202= | Silent (SNP) | VAF 59/173 reads (34%) | catalogued as COSV57422918; called by muse, mutect2, varscan2
- PRAG1 | c.2466C>T p.S822= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as COSV58160328; called by muse, mutect2, varscan2
- PREX2 | c.1743T>C p.H581= | Silent (SNP) | VAF 13/175 reads (7%) | catalogued as COSV55766601; called by muse, mutect2
- PRICKLE2 | c.1651C>A p.R551= (on ENST00000295902; = p.R495= on NM_198859.4) | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as COSV55765887; called by muse, mutect2, varscan2
- PRMT5 | c.1407T>C p.T469= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV53545839; called by muse, mutect2
- PRRG1 | c.624T>C p.I208= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV66157417; called by muse, mutect2, varscan2
- PRUNE1 | c.981C>T p.T327= | Silent (SNP) | VAF 38/382 reads (10%) | catalogued as rs990444457, COSV54846829; called by muse, mutect2
- PSMD1 | c.2055A>G p.Q685= | Silent (SNP) | VAF 19/205 reads (9%) | catalogued as rs774787689, COSV58078293; called by muse, mutect2
- RALGAPA2 | c.2748C>T p.A916= | Silent (SNP) | VAF 68/145 reads (47%) | catalogued as rs539866650, COSV52495885; called by muse, mutect2, varscan2
- RAPGEF1 | c.2433G>A p.Q811= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV64698348; called by muse, mutect2
- RHPN2 | c.1710G>A p.T570= | Silent (SNP) | VAF 78/157 reads (50%) | catalogued as rs764810877, COSV54278168, COSV54286483; called by muse, mutect2, varscan2
- RICTOR | c.3852G>A p.S1284= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs536774546, COSV57121217; called by muse, mutect2, varscan2
- RNF40 | c.1752C>A p.P584= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV61214614; called by muse, mutect2, varscan2
- RPL28 | c.219T>C p.P73= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV59804738; called by muse, mutect2, varscan2
- RPUSD1 | c.622C>T p.L208= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs1567375946, COSV50100354; called by muse, mutect2, varscan2
- RSPO4 | c.435C>T p.G145= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs201319898, COSV54080900; called by muse, mutect2
- RTL5 | c.720C>A p.A240= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV65453230; called by muse, mutect2
- SAMD9 | c.1449A>G p.L483= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as COSV66074794; called by muse, mutect2
- SDCCAG8 | c.654T>C p.S218= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as COSV59408314; called by muse, mutect2, varscan2
- SEC31B | c.270C>T p.G90= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs145607458; called by muse, mutect2, varscan2
- SETX | c.7665T>C p.L2555= | Silent (SNP) | VAF 45/175 reads (26%) | catalogued as COSV56383735; called by muse, mutect2, varscan2
- SLC12A6 | c.1848T>C p.N616= (on ENST00000354181 / NM_001365088.1; = p.N565= on NM_005135.2) | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as COSV51625593; called by muse, mutect2
- SLC15A4 | c.1662T>A p.S554= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as COSV57161261; called by muse, mutect2
- SLC35F4 | c.1011G>T p.V337= (on ENST00000339762 / NM_001352015.2; = p.V301= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as COSV60264389; called by muse, mutect2, varscan2
- SLC49A4 | c.1395A>G p.E465= | Silent (SNP) | VAF 14/530 reads (3%) | catalogued as COSV53746747; called by muse, mutect2
- SLC4A1 | c.2352C>A p.P784= | Silent (SNP) | VAF 43/153 reads (28%) | catalogued as COSV52259729; called by muse, mutect2, varscan2
- SLC9B2 | c.606C>T p.G202= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as rs376080494, COSV60018890; called by muse, mutect2, varscan2
- SNX7 | c.442C>T p.L148= | Silent (SNP) | VAF 89/244 reads (36%) | catalogued as rs1348156191, COSV60268064; called by muse, mutect2, varscan2
- SPAG7 | c.363C>T p.Y121= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV52777193; called by muse, mutect2, varscan2
- SPEN | c.7200T>C p.S2400= | Silent (SNP) | VAF 10/261 reads (4%) | catalogued as COSV65361194; called by muse, mutect2
- SPRR2B | c.132C>T p.P44= | Silent (SNP) | VAF 88/945 reads (9%) | catalogued as COSV58797013; called by muse, mutect2
- SPSB1 | c.642T>C p.S214= | Silent (SNP) | VAF 85/231 reads (37%) | catalogued as rs1295772378, COSV60162987; called by muse, mutect2, varscan2
- SPTY2D1 | c.1245C>A p.S415= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV60473730; called by muse, mutect2, varscan2
- SSTR1 | c.36C>A p.S12= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57455745; called by muse, varscan2
- TAF4 | c.1548G>A p.R516= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV53337177; called by muse, mutect2, varscan2
- TAS2R41 | c.403T>C p.L135= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as COSV68765188; called by muse, mutect2
- TEX2 | c.819T>C p.D273= | Silent (SNP) | VAF 49/293 reads (17%) | catalogued as COSV51980445; called by muse, mutect2, varscan2
- THRB | c.144G>A p.T48= | Silent (SNP) | VAF 161/421 reads (38%) | catalogued as rs138865141; called by muse, mutect2, varscan2
- TMEM145 | c.357T>C p.C119= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV56625018; called by muse, mutect2, varscan2
- TNXB | c.819C>T p.D273= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs370024421; called by muse, mutect2, varscan2
- TPX2 | c.2061G>A p.Q687= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV55919174; called by muse, mutect2, varscan2
- TRIM4 | c.1404G>A p.L468= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV62468999; called by muse, mutect2
- TTN | c.43419C>T p.F14473= (on ENST00000591111; = p.F7049= on NM_003319.4) | Silent (SNP) | VAF 5/143 reads (3%) | catalogued as COSV60017096; called by muse, mutect2
- UGT2B11 | c.1440C>A p.A480= | Silent (SNP) | VAF 15/510 reads (3%) | catalogued as COSV71423286; called by muse, mutect2
- UPP2 | c.627C>A p.L209= | Silent (SNP) | VAF 78/191 reads (41%) | catalogued as COSV50046792, COSV50047832; called by muse, mutect2, varscan2
- USP31 | c.2061G>A p.S687= | Silent (SNP) | VAF 7/195 reads (4%) | catalogued as rs1197023543, COSV54851685; called by muse, mutect2
- VPS13B | c.1641T>C p.T547= | Silent (SNP) | VAF 153/382 reads (40%) | catalogued as rs750517242, COSV62018899; called by muse, mutect2, varscan2
- VWA8 | c.5062C>T p.L1688= | Silent (SNP) | VAF 49/288 reads (17%) | catalogued as COSV101022450, COSV64996033; called by muse, mutect2, varscan2
- WFS1 | c.975C>T p.N325= | Silent (SNP) | VAF 86/534 reads (16%) | catalogued as rs141177727; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- XIRP2 | c.981T>C p.Y327= (on ENST00000628543; = p.Y502= on NM_152381.6) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV54696528; called by muse, mutect2
- ZC3H4 | c.429G>A p.S143= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV53412607; called by muse, mutect2, varscan2
- ZMYND12 | c.178C>T p.L60= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV65341956; called by muse, mutect2, varscan2
- ZNF175 | c.1269A>G p.E423= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV51795287; called by muse, mutect2
- ZNF618 | c.1308G>A p.E436= (on ENST00000374126 / NM_001318042.2; = p.E343= on NM_133374.2) | Silent (SNP) | VAF 11/283 reads (4%) | catalogued as COSV55920469; called by muse, mutect2
- ZNF667 | c.1812A>G p.T604= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV52633619; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81157022 G>A | 3'Flank (SNP) | VAF 34/114 reads (30%) | catalogued as rs199512473; called by muse, mutect2, varscan2
- AGAP7P | n.988del | RNA (DEL) | VAF 51/275 reads (19%) | called by mutect2, pindel, varscan2
- AMACR | c.739+1245C>T | Intron (SNP) | VAF 50/215 reads (23%) | catalogued as COSV100163276; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+5298C>T | Intron (SNP) | VAF 52/323 reads (16%) | catalogued as COSV56138983; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417415 G>A | 3'Flank (SNP) | VAF 81/192 reads (42%) | catalogued as rs779676773; called by muse, mutect2, varscan2
- CCT4 | c.-2C>T | 5'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1012521917, COSV101075403; called by muse, mutect2, varscan2
- DCHS2 | n.8184C>T | RNA (SNP) | VAF 100/230 reads (43%) | catalogued as COSV61771044; called by muse, mutect2, varscan2
- KAT2B | c.*8del | 3'UTR (DEL) | VAF 9/23 reads (39%) | catalogued as rs750062124; called by mutect2, varscan2
- LAMA4 | c.195+72C>T | Intron (SNP) | VAF 34/107 reads (32%) | catalogued as COSV54569503; called by muse, mutect2, varscan2
- LINC00922 | n.773A>G | RNA (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2, varscan2
- MIR18A | n.42C>T | RNA (SNP) | VAF 11/348 reads (3%) | called by muse, mutect2
- MRPS17P9 | n.250A>G | RNA (SNP) | VAF 25/79 reads (32%) | catalogued as rs372127161; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120791 del A | 3'Flank (DEL) | VAF 14/72 reads (19%) | catalogued as rs769032953; called by mutect2, varscan2
- SLC7A2 | c.1195+357C>T | Intron (SNP) | VAF 95/278 reads (34%) | catalogued as rs777754869, COSV50251716; called by muse, mutect2, varscan2
- SSPOP | n.11067C>T | RNA (SNP) | VAF 5/18 reads (28%) | catalogued as rs377441983; called by muse, mutect2, varscan2
- TGIF1 | c.-65G>A | 5'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57907383, COSV57907421; called by muse, mutect2
- TRUB1 | c.-1T>C | 5'UTR (SNP) | VAF 5/89 reads (6%) | catalogued as rs1477562893, COSV100076226; called by muse, mutect2
- TSHZ1 | c.*1C>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | catalogued as rs765227721, COSV59019674; called by muse, mutect2, varscan2
- TTN | c.34265-230G>A | Intron (SNP) | VAF 8/14 reads (57%) | catalogued as rs1235535488, COSV60017188; called by mutect2, varscan2
- UVSSA | c.*8790C>A | 3'UTR (SNP) | VAF 38/220 reads (17%) | catalogued as rs532123027, COSV61348706; called by muse, varscan2
- ZSWIM4 | chr19:13836448 C>T | 3'Flank (SNP) | VAF 31/87 reads (36%) | catalogued as rs1017144560; called by muse, mutect2, varscan2
